Gene-level copy-number profile of tumor specimen TCGA-06-6390-01A from TCGA case TCGA-06-6390, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.4 years (21,328 days).
Specimen TCGA-06-6390-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.006c80c2-0273-42ab-8849-60700f462efc.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-6390-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 358 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0d903f13-27f7-42db-a136-73d183491c58

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 30; copy number 1: 2,384; copy number 2: 9,164; copy number 3: 4,802; copy number 4: 38,053; copy number 5: 1,066; copy number 6: 267; copy number 7: 4,224; copy number 8: 6; copy number 11: 3; copy number 12: 1; copy number 13: 21; copy number 14: 29; copy number 15: 1; copy number 16: 208; copy number 17: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-06-6390-01A-11D-1694-01): tumor purity 0.45, ploidy 3.76, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 30 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:185,918,140–186,289,681, 11 genes (within-gene range 0–2): AC096659.1, RNU4-64P, TLR3, FAM149A, AC104070.1, RPSAP70, ORAOV1P1, FLJ38576, CYP4V2, KLKB1, F11.
- chr4:188,990,715–189,002,075, 1 gene: AC122138.1.
- chr6:169,419,969–169,702,047, 1 gene (within-gene range 0–2): AL031315.1.
- chr6:169,457,212–170,200,258, 17 genes (within-gene range 0–2): WDR27, C6orf120, PHF10, AL354892.2, AL354892.1, TCTE3, ERMARD, AL354892.3, LINC00242, LINC00574, AL049612.1, AL603783.1, AL596442.4, AL596442.3, AL596442.1, AL596442.2, RPL12P23.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 269 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:40,140,926–40,142,876, 1 gene, copy number 15: LINC02555.
- chr12:41,188,320–41,774,671, 6 genes, copy number 17: PDZRN4, AC090531.1, RNA5SP360, MTND2P17, MTND1P24, LINC02400.
- chr12:42,069,935–42,238,349, 3 genes, copy number 11: AC023513.1, GXYLT1, YAF2.
- chr12:56,951,431–59,064,238, 79 genes, copy number 16 (within-gene range 3–16) (broad region; genes not listed).
- chr12:61,668,302–62,279,150, 5 genes, copy number 13 (within-gene range 5–13): AC090629.1, TAFA2, RPL21P104, KRT8P19, RPS3P6.
- chr12:62,755,227–62,756,233, 1 gene, copy number 12: GAPDHP44.
- chr12:67,571,197–67,589,987, 1 gene, copy number 13: LINC02442.
- chr12:67,753,701–71,118,247, 75 genes, copy number 16 (broad region; genes not listed).
- chr12:71,709,171–79,559,166, 98 genes, copy number 13–16 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
